Somatic mutation profile of tumor specimen TARGET-10-PANVIB-09A (aliquot TARGET-10-PANVIB-09A-01D) from TARGET case TARGET-10-PANVIB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,040 days).
Specimen TARGET-10-PANVIB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ad7791-f6c1-4c68-8d56-d66b38be3b71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVIB-14A (Bone Marrow Normal), aliquot TARGET-10-PANVIB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecde9939-8886-48a0-99c0-7cead35b5752

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GSDMD | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.133); catalogued as rs1405530233; called by muse, mutect2, varscan2
- LAMA2 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs138765295, COSV70349027; called by muse, mutect2, varscan2
- MYC | c.1105G>A p.E369K (on ENST00000377970; = p.E384K on NM_002467.6) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52372750; called by muse, mutect2
- OVOL3 | c.550C>T p.R184C (on ENST00000585332; = p.R160C on NM_001302757.1) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1452194241; called by muse, mutect2, varscan2
- SETD2 | c.5056C>T p.R1686W | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100340335; called by muse, mutect2
- GPR158 | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY2F | c.1099A>C p.M367L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- OR13C3 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRDV2 | chr14:22423041 ins CGTT | Frame Shift Ins (INS) | VAF 33/143 reads (23%) | called by mutect2, pindel, varscan2
- VEGFC | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- IFNA6 | c.*152G>A | 3'UTR (SNP) | VAF 4/53 reads (8%) | catalogued as rs892827796; called by muse, mutect2
